Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A5GU, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A5GU-06A (Metastatic).

[page 1 of 2]
***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) LEFT HIP, SKIN ELLIPSE:

METASTATIC MELANOMA INVOLVING SUBCUTANEOUS TISSUE WITH EXTENSIVE NECROSIS, MARGINS FREE (WITHIN 1.1 MM FROM CLOSEST LATERAL MARGIN, A3). (SEE COMMENT)
TUMOR SIZE: 7.9 X 6.0 MM (AS MEASURED ON SLIDE).
Tumor borders pushing.

(B) RIGHT AXILLA, EXCISION:

METASTATIC MELANOMA INVOLVING ONE OF TWO LYMPH NODES (1/2). (SEE COMMENT)
Largest tumor deposit size: 20.0 x 16.0 mm (per gross description).
Location: Subcapsular and intraparenchymal.
EXTRACAPSULAR EXTENSION: PRESENT.
Exogenous black pigment, consistent with tattoo, involving one lymph node.

COMMENT

In parts (A) and (B), the tumor cells demonstrate focal melanin pigment (specimen A) and similar morphology (specimen A and B) to the patient's known melanoma of the right shoulder (see case _____), which supports the above diagnoses.

GROSS DESCRIPTION

(A) LEFT HIP NODULE, SHORT STITCH SUPERIOR, LONG STITCH LATERAL – A 2.4 x 0.6 cm tan-pink skin ellipse with subcutis, excised to a depth of 1.5 cm and oriented by the surgeon with a short stitch designating the superior tip and a long stitch designating the lateral tissue edge. The specimen is inked and serially sectioned to reveal a 0.7 x 0.6 x 0.5 cm subcutaneous nodule that grossly appears to abut the deep margin. The specimen is entirely submitted in A.

INK CODE: Blue – lateral half; orange – medial half.

SECTION CODE: A1, superior tip; A2, inferior tip; A3, A4, remaining central sections, entirely submitted from superior to inferior.

(B) MASS RIGHT AXILLA, FOR _____ - Two tan-pink possible lymph nodes (2.0 x 1.6 x 1.4 cm and 2.0 x 1.4 x 0.8 cm). The larger possible lymph node appears grossly positive for tumor. A portion of the larger lymph node is submitted for _____ studies and tumor bank. The remaining specimen is entirely submitted in B.

SECTION CODE: B1, B2, remainder of the larger possible lymph node; B3, B4, the smaller possible lymph node, entirely submitted.

CLINICAL HISTORY

Metastatic melanoma.

SNOMED CODES

T-02480, T-C4710, M-87206

"Some tests reported here may have been developed and performance characteristics determined by _____ specifically cleared or approved by the U.S. Food and Drug Administration."

_____ . These tests have not been

Entire report and diagnosis completed by: _____

Start of ADDENDUM

ICD-0-3

Melanoma, malignant NOS 8720/3
Site: Axillary Lymph Node C77.3
JW 4/4/13

[page 2 of 2]
ADDENDUM

This modified report is being issued to report special studies/IHC/Molecular studies.

COMMENT

At the request of the clinician Dr. _____ and per _____ protocol, immunohistochemical studies for panmelanocytic cocktail (HMB45, anti-Mart-1, anti-tyrosinase) was performed on tissue block B1. The tumor cells are strongly reactive for panmelanocytic cocktail.

Entire report and diagnosis completed by:

-----END OF REPORT-----

/ Medicine

Criteria	met	Yes	No
Stiff Discrepancy			✓
Prior Discrepancy history			✓

Source: NCI Genomic Data Commons file 684f69ec-574c-48e6-9486-b17b61a00b8d (TCGA-D3-A5GU.61348895-5985-4B59-9B2A-E81B6481372D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).